CCDI case PBCHEX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/606af017-c2bf-46cd-a5d7-56fd20983323

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,309 days).

Biospecimens (3 samples)
- Sample 0DRXE6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRXED: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DRXET: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
